Gene-level copy-number profile of tumor specimen AP-QD4Q-9B from APOLLO case AP-QD4Q, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3.
Specimen AP-QD4Q-9B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 95d7e01c-3275-415a-b887-78c56143caed.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-QD4Q-H9 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/5d088ea5-4459-459e-9311-3e272d8364df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 2,330; copy number 2: 55,886; copy number 3: 150.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr9:40,767,870–40,883,763, 2 genes (within-gene range 0–2): AL353626.1, AL353626.2.
- chr9:65,189,995–66,043,342, 21 genes: BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2.
- chr14:18,333,726–18,596,310, 8 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9.
- chr21:10,640,028–13,016,692, 3 genes: AF254982.1, IGHV1OR21-1, AP001464.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,476. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
